Gene-level copy-number profile of tumor specimen ALCH-B1P8-TTP1-A from ALCHEMIST case ALCH-B1P8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.5 years (20,265 days).
Specimen ALCH-B1P8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 32d04133-40c0-495f-815e-f8066e0030f4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1P8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/1236e3fc-266e-480c-8679-3a170a14a817

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 7,608; copy number 2: 47,514; copy number 3: 3,094; copy number 4: 120; copy number 5: 54; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,524,385–52,535,054, 1 gene (within-gene range 0–2): NT5DC2.
- chr7:5,274,369–5,306,870, 1 gene (within-gene range 0–2): SLC29A4.
- chr7:129,783,370–129,785,185, 1 gene: AC084864.1.
- chr17:3,923,870–3,964,464, 1 gene: ATP2A3.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr22:30,356,635–30,378,658, 1 gene (within-gene range 0–2): CCDC157.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:45,391,626–45,392,205, 1 gene, copy number 6: ELK1P1.
- chr7:46,476,457–47,079,128, 10 genes, copy number 5: AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1.
- chr22:18,906,028–18,947,732, 3 genes, copy number 6 (within-gene range 3–6): DGCR6, AC007326.4, PRODH.
- chr22:20,602,595–21,070,097, 29 genes, copy number 5: SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP.
- chr22:35,066,136–35,553,999, 15 genes, copy number 5: ISX, LINC01399, Z99755.2, Z99755.1, RNU7-167P, HMGXB4, AL008635.1, TOM1, MIR3909, MIR6069, HMOX1, MCM5, AL022334.1, AL022334.2, RASD2.

Autosomal genes at a single copy (total copy number 1): 5,388. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
